Somatic mutation profile of tumor specimen TCGA-50-5936-01A (aliquot TCGA-50-5936-01A-11D-1625-08) from TCGA case TCGA-50-5936, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 58.1 years (21,238 days).
Specimen TCGA-50-5936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 275640ab-8485-40fc-a9b7-bfad6eb75796.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5936-11A (Solid Tissue Normal), aliquot TCGA-50-5936-11A-01D-1625-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa1256ab-223b-4af0-90d1-6cd404fcb585

The open-access MAF lists 123 somatic variants for this specimen: 96 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 26, Nonsense Mutation 8, Frame Shift Ins 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACADM | c.146A>C p.Q49P | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV63719505; called by muse, mutect2, varscan2
- ADGRV1 | c.781A>T p.S261C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67977334; called by muse, mutect2, varscan2
- AKR1D1 | c.80C>G p.S27* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV54335901; called by muse, mutect2, varscan2
- ANK3 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55042273; called by muse, mutect2, varscan2
- AP002748.5 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 6/100 reads (6%) | catalogued as CM031130, COSV59146717; called by muse, mutect2
- APOB | c.5298C>G p.F1766L | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51921313, COSV51939971; called by muse, mutect2, varscan2
- BACH2 | c.1088A>T p.H363L | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57582798; called by muse, mutect2, varscan2
- BLOC1S4 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs1459773819, COSV57900763; called by muse, mutect2
- BRF1 | c.1028T>G p.L343R | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100527311; called by muse, mutect2, varscan2
- CD72 | c.894G>T p.W298C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52409731, COSV99427616; called by muse, mutect2, varscan2
- CD99 | c.121A>T p.T41S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.874); catalogued as COSV66990904; called by muse, mutect2, varscan2
- CECR2 | c.2884G>A p.E962K (on ENST00000342247 / NM_001290047.2; = p.E779K on NM_001290046.1) | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1212118850, COSV52835245; called by muse, mutect2, varscan2
- CMSS1 | c.696T>G p.F232L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV70435362; called by muse, mutect2, varscan2
- CNOT11 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV99179289; called by muse, varscan2
- CNOT11 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99078783; called by muse, varscan2
- CRISP3 | c.253T>A p.S85T (on ENST00000371159 / NM_001368123.1; = p.S67T on NM_006061.4) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.347); catalogued as COSV53818777; called by muse, mutect2
- CXCR1 | c.601G>C p.V201L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV99826334; called by muse, mutect2
- CYP7A1 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766417104, COSV56962025; called by muse, mutect2, varscan2
- DMBX1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263612912, COSV100760772; called by muse, mutect2
- DNAH9 | c.5795T>A p.L1932* | Nonsense Mutation (SNP) | VAF 13/29 reads (45%) | catalogued as COSV52331628; called by muse, mutect2, varscan2
- DOCK4 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.258); catalogued as COSV70313634; called by muse, mutect2, varscan2
- DSG3 | c.377C>A p.T126K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.475); catalogued as COSV57123865; called by muse, mutect2, varscan2
- EFHB | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.045); catalogued as COSV55544400; called by muse, mutect2, varscan2
- EPRS1 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as COSV65096932; called by muse, mutect2, varscan2
- ETS1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1045241125, COSV60091363; called by muse, mutect2, varscan2
- FAM160B2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs1325823495, COSV57156757, COSV99248761; called by muse, mutect2, varscan2
- FCN2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52475695; called by muse, mutect2, varscan2
- FLT3LG | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV52618099; called by muse, varscan2
- FRK | c.1408T>C p.W470R | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73383786; called by muse, mutect2, varscan2
- GINS4 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV52530749; called by muse, mutect2, varscan2
- GOT1 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65146987, COSV65147187; called by muse, mutect2, varscan2
- GTF3C1 | c.4663G>A p.D1555N | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.455); catalogued as rs369166362, COSV62238524; called by muse, mutect2, varscan2
- GUCY2C | c.2397G>A p.M799I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV53786063; called by muse, mutect2, varscan2
- HSD3B1 | c.874T>C p.Y292H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248419285, COSV52489473; called by muse, mutect2, varscan2
- ITGB5 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037360132, COSV56146262; called by muse, mutect2, varscan2
- KDM3B | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070095, COSV58687363; called by muse, mutect2, varscan2
- KEAP1 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 29/86 reads (34%) | catalogued as COSV50260393; called by muse, mutect2, varscan2
- KNTC1 | c.4807A>C p.N1603H | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.478); catalogued as COSV61078623; called by muse, mutect2, varscan2
- KPNA2 | c.1479G>C p.E493D | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57856776; called by muse, mutect2, varscan2
- MAGEE1 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV63908632; called by muse, mutect2
- MAP3K11 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV58418054; called by muse, mutect2, varscan2
- MAP3K13 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV99407130; called by muse, mutect2
- MAP3K5 | c.1820C>G p.S607C | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV62886498; called by muse, mutect2, varscan2
- ME3 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV60164111; called by muse, mutect2
- METTL4 | c.46C>G p.L16V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV55246684; called by muse, mutect2, varscan2
- MIOS | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs1404820299, COSV100402485, COSV60766639; called by muse, mutect2, varscan2
- MLC1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61115695; called by muse, mutect2, varscan2
- MLF1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV63032299; called by muse, mutect2
- MSANTD2 | c.1283A>G p.E428G (on ENST00000374979 / NM_001308027.2; = p.E376G on NM_024631.4) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53446805; called by muse, mutect2, varscan2
- MYO1H | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755229590, COSV60442476, COSV60444565; called by muse, mutect2, varscan2
- NAV1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV55213490; called by muse, mutect2, varscan2
- NAV1 | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV55213502; called by muse, mutect2, varscan2
- NDUFA8 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV65653227; called by muse, mutect2, varscan2
- NLRP3 | c.523C>A p.H175N | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV60219045; called by muse, mutect2, varscan2
- NOS1 | c.3043C>T p.R1015W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs565699307, COSV57605697; called by muse, mutect2
- NR5A2 | c.345A>T p.Q115H (on ENST00000367362 / NM_205860.3; = p.Q69H on NM_003822.5) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52644188; called by muse, mutect2, varscan2
- NRG1 | c.947_948insG p.N316Kfs*6 (on ENST00000405005 / NM_013964.5; = p.N321Kfs*6 on NM_013956.5) | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | catalogued as COSV99828412; called by mutect2, pindel, varscan2
- OR2A2 | c.902A>C p.H301P | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.162); catalogued as COSV68870917; called by muse, mutect2, varscan2
- PCDH10 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as COSV52086607, COSV99993510; called by muse, mutect2, varscan2
- PCDHB14 | c.2339G>T p.G780V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV53386140; called by muse, mutect2, varscan2
- PCDHGB2 | c.2112C>G p.F704L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53891940; called by muse, mutect2, varscan2
- PCGF6 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV100461986; called by muse, mutect2, varscan2
- PDGFA | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100627315; called by muse, mutect2, varscan2
- PHKB | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749255658, COSV54513043; called by muse, mutect2, varscan2
- PHLDB2 | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201756409, COSV67307235; called by muse, mutect2, varscan2
- PLPPR4 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV64564017; called by muse, mutect2, varscan2
- PRKG1 | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100907484, COSV64765800; called by muse, mutect2, varscan2
- PRMT8 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1431310921, COSV54211221; called by muse, mutect2, varscan2
- ROBO1 | c.2166C>A p.D722E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV71391374; called by muse, mutect2
- RP1L1 | c.4403A>C p.Q1468P | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV66751267; called by muse, mutect2, varscan2
- SLC22A16 | c.1067C>A p.T356K | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV57926802; called by muse, mutect2, varscan2
- SMARCA4 | c.1147C>T p.Q383* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV60785495; called by muse, varscan2
- SPATA31D1 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760679229, COSV61192230; called by muse, mutect2, varscan2
- SRCAP | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52666813; called by muse, mutect2, varscan2
- SRRM2 | c.2521C>T p.H841Y | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1010174542, COSV57067114; called by muse, mutect2, varscan2
- TANC1 | c.4436C>G p.P1479R | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.23); catalogued as COSV55082126; called by muse, mutect2, varscan2
- THOP1 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310564; called by muse, mutect2
- TINAG | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.955); catalogued as COSV52504991; called by muse, mutect2, varscan2
- TRAPPC11 | c.701G>T p.S234I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV58214274; called by muse, mutect2, varscan2
- TRPS1 | c.3293C>A p.P1098H (on ENST00000220888 / NM_001330599.2; = p.P1111H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55224141; called by muse, mutect2, varscan2
- TSHZ3 | c.2536G>C p.D846H | Missense Mutation (SNP) | VAF 68/123 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53663076; called by muse, mutect2, varscan2
- TSR1 | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs766742085, COSV56783619; called by muse, mutect2
- TUBGCP6 | c.215T>C p.M72T | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV50536141; called by muse, mutect2, varscan2
- URB2 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs764093845, COSV50980970; called by muse, mutect2, varscan2
- USH2A | c.2836A>G p.T946A | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as rs754932972, COSV56321662; ClinVar: uncertain significance; called by muse, mutect2
- VARS1 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs766331691, COSV63304147; called by muse, mutect2, varscan2
- WIPF1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV55810797; called by muse, mutect2, varscan2
- ZC3H13 | c.1589G>A p.G530D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs1392419369, COSV54446836; called by muse, mutect2, varscan2
- ZFPM2 | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV68272945, COSV68277668; called by muse, mutect2, varscan2
- ZMIZ2 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV54805667, COSV54811728; called by muse, mutect2, varscan2
- ZNF250 | c.1480C>G p.L494V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52967803; called by muse, mutect2, varscan2
- ZNF48 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV60782206; called by muse, mutect2, varscan2
- ZNF48 | c.579C>G p.I193M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV60782217; called by muse, mutect2, varscan2
- DLC1 | c.1669dup p.S557Ffs*63 (on ENST00000276297 / NM_001348081.2; = p.S120Ffs*63 on NM_006094.5) | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- IGHV3-73 | c.164G>T p.W55L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LIF | c.230del p.N77Tfs*10 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- ABCG5 | c.1302C>A p.G434= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV53210962, COSV99575375; called by muse, mutect2, varscan2
- AC005833.1 | c.1272C>T p.I424= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs780520873, COSV52894203; called by muse, mutect2, varscan2
- ADAMTS7 | c.3753C>T p.S1251= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs774059730, COSV66305624; called by muse, mutect2, varscan2
- AGFG2 | c.948C>T p.D316= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs550739522, COSV53543815; called by muse, mutect2, varscan2
- DHX57 | c.540A>T p.T180= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54882111; called by muse, mutect2, varscan2
- DUSP15 | c.210C>T p.F70= (on ENST00000278979 / NM_001320479.1; = p.F73= on NM_080611.4) | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV54064707; called by muse, mutect2, varscan2
- F13B | c.1599A>T p.G533= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV66372004; called by muse, mutect2, varscan2
- GALNT2 | c.1593G>C p.L531= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV64192596; called by muse, mutect2, varscan2
- GPR22 | c.951G>A p.L317= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV51741722; called by muse, mutect2, varscan2
- H2AC20 | c.36C>T p.R12= | Silent (SNP) | VAF 40/149 reads (27%) | catalogued as rs781902280, COSV58611132; called by muse, mutect2, varscan2
- IGHV3-53 | c.15G>A p.L5= | Silent (SNP) | VAF 34/120 reads (28%) | called by muse, mutect2, varscan2
- INTS13 | c.1614C>T p.T538= | Silent (SNP) | VAF 69/294 reads (23%) | catalogued as COSV53900952; called by muse, mutect2, varscan2
- ITGA10 | c.2026C>T p.L676= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV65195831; called by muse, mutect2, varscan2
- JCAD | c.2967C>G p.P989= | Silent (SNP) | VAF 39/146 reads (27%) | catalogued as rs372613979, COSV64757673, COSV64760497; called by muse, mutect2, varscan2
- KCNV1 | c.798C>T p.D266= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV52084490; called by mutect2, varscan2
- NGLY1 | c.765A>T p.G255= | Silent (SNP) | VAF 30/113 reads (27%) | catalogued as COSV54983417; called by muse, mutect2, varscan2
- NUFIP2 | c.1695C>T p.Y565= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs150088850; called by muse, mutect2, varscan2
- OR8B8 | c.624T>G p.G208= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV60143567, COSV60144296; called by muse, mutect2, varscan2
- REPS1 | c.1458G>T p.V486= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV57808418; called by muse, mutect2, varscan2
- SUPT5H | c.1830A>G p.R610= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV63238249; called by muse, mutect2, varscan2
- TMPRSS15 | c.42C>T p.L14= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV99517905; called by muse, mutect2, varscan2
- TNKS | c.2850T>G p.A950= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as COSV60050872; called by muse, mutect2, varscan2
- USP8 | c.1161T>G p.S387= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV56161800; called by muse, mutect2, varscan2
- XIRP2 | c.6474G>A p.K2158= (on ENST00000628543; = p.K2333= on NM_152381.6) | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV54679701; called by muse, mutect2, varscan2
- ZFPM2 | c.2526G>T p.R842= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV101023213; called by muse, mutect2
- ZP4 | c.1200C>A p.I400= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs776928138, COSV63910660; called by muse, mutect2, varscan2
- OR5H15 | c.925+10C>T | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as COSV62947237; called by muse, mutect2, varscan2
